Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IV, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IV-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Final Diagnosis

- A LYMPH NODE, HEPATIC ARTERY, EXCISION:
One lymph node, negative for metastatic carcinoma (0/1).
- B PANCREAS AND SPLEEN, SUBTOTAL PANCREATECTOMY AND SPLENECTOMY:
Pancreatic endocrine neoplasm, grade 2.
Tumor size: 3 x 2.5 x 2 cm.
Surgical margins: Free of tumor.
Necrosis: present.
Mitotic rate: 7/10 HPFs.
Fifteen regional lymph nodes with no evidence of metastasis.
Unremarkable spleen.
See Key Pathological Findings.
- C ACCESSORY SPLEEN, "SPLENULE", EXCISION:
Unremarkable splenic parenchyma.
- D GALLBLADDER, CHOLECYSTECTOMY:
Chronic cholecystitis and cholesterosis.
No evidence of dysplasia or malignancy.

I, _____ the attending pathologist, personally reviewed all
slides and / or materials and rendered the final diagnosis. Electronically
Signed Out by _____

Key Pathological Findings

B: Pancreas Endocrine

SPECIMEN:

Tail of pancreas

Spleen

SPECIMEN:

Splenectomy

TUMOR SITE:

Pancreatic tail

TUMOR SIZE:

Greatest dimension: 3.0 cm

Additional dimensions: 2.5 x 2.0 cm

TUMOR FOCALITY:

Unifocal

HISTOLOGIC TYPE:

ICD O.3

Neuroendocrine carcinoma, NOS 8246/3
Site: Pancreatic tail C25.2
Jd 4/16/14

[page 2 of 4]
Well-differentiated neuroendocrine tumor
WORLD HEALTH ORGANIZATION CLASSIFICATION:
Well-differentiated endocrine tumor, uncertain behavior
FUNCTIONAL TYPE:
Cannot be assessed
MITOTIC ACTIVITY:
Greater than or equal to 2 mitoses/10 HPF to 10 mitoses/10 HPF; number of mitoses per 10
HPF: 7 mitoses / 10 high power fields
Ki67 LABELING INDEX:
3%-20% Ki67-positive cells
TUMOR NECROSIS:
Present
MICROSCOPIC TUMOR EXTENSION:
Tumor is confined to pancreas
MARGINS:
Margina uninvolved by tumor
Distance of tumor from closest margin: 0.2 mm
LYMPH-VASCULAR INVASION:
Present
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis
Number examined: 16
Number involved: 0
DISTANT METASTASIS
ADDITIONAL PATHOLOGIC FINDINGS:
PANIN IIa
ANCILLARY STUDIES:
The neoplastic cells are positive for synaptophysin, focally positive for chromogranin by
immunohistochemistry. The Ki-67 immunostain is positive in approximately 15% of the
neoplastic cells.
*COMMENT(S):
B2-7 adequate for molecular studies.

Specimen(s) Received

A HEPATIC ARTERY LYMPH NODE
B SUBTOTAL PANCREATECTOMY AND SPLENECTOMY FS
C SPLENULE
D GALLBLADDER GROSSLY CHECK FOR POLYP

Clinical History

Y/O FEMALE MORBID OBESITY, HM-ASTHMA.

Preoperative Diagnosis

PANCREATIC NEUROENDOCRINE TUMOR.

[page 3 of 4]
Intraoperative Consultation

FSB1 SUBTOTAL PANCREATECTOMY AND SPLENECTOMY:
Pancreatic margin, no evidence of malignancy.

GROSS EXAMINATION

D GALLBLADDER GROSSLY CHECK FOR POLYP:
Partially calcified mucosal polyps, measuring 3 mm to 5 mm.

FSD1 GALLBLADDER GROSSLY CHECK FOR POLYP:
Largest polyp no evidence of malignancy.

Intradepartmental Consultation: The case was also reviewed by MD, who concurs with the above interpretation (FSD1).

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

I, I.D., have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh labeled "hepatic artery lymph node." The specimen consists of a 2.0 x 1.5 x 1.0, moderately firm gray tan irregular lymph node which is serially sectioned and entirely submitted as A1-A2.

B. Specimen B is received fresh for frozen section analysis labeled "subtotal pancreatectomy and splenectomy." The specimen consists of a subtotal pancreatectomy (8.0 x 4.0 x 2.5 cm) attached to a grossly unremarkable spleen (14.0 x 8.0 x 6.0 cm). Both specimens are adherent to a moderate amount of fat. The pancreatic margin of resection is stapled. The staples are removed and the underlying tissue is removed tangentially and entirely submitted on frozen section as FSB1. The pancreatic duct is markedly dilated but is probe-patent for approximately 2 cm where it is filled with a soft brown tan protruding tissue (possible tumor). The end of the pancreas which attaches to the spleen is markedly indurated and exhibits a gray white smooth ill-defined mass (3.0 x 2.5 x 2.0 cm) abutting the soft tissue margin of resection and is approximately 4 cm from the pancreatic margin of resection. The mass at this point totally occludes the pancreatic duct. The mass occupies approximately 75% of the pancreas. The random pancreatic parenchyma is lobulated gray tan grossly unremarkable.

The capsule of the spleen is brown tan and intact. The cut surface exhibits a soft red brown tissue with grossly unremarkable parenchyma. Sectioning of the adipose tissue isolates no definitive lymph nodes.

A representative section of the tumor is submitted to Tissue Procurement Laboratory.

Representative sections are submitted as:

B2: Mirror image of tumor submitted to Tissue Bank
B3-B6: Sections of tumor showing relationship to soft tissue margin of resection

[page 4 of 4]
B7-B8: Sections of tumor showing relationship to pancreatic duct
B9: Grossly unremarkable pancreatic parenchyma
B10: Grossly unremarkable spleen
B11-B26: Representative sections of adipose tissue

C. Specimen C is received fresh labeled "splenule." The specimen consists of what grossly appears to be a lobule of splenic tissue partially covered by adipose tissue (2.5 x 2.0 x 2.0 cm). The overlying adipose tissue is marked with black ink. The specimen is serially sectioned and reveals a red brown grossly unremarkable splenic parenchyma. Representative sections submitted as C1.

D. Specimen D is received fresh for frozen section analysis labeled "gallbladder grossly check for polyps. The specimen consists of a club-shaped gallbladder (8.0 x 3.0 x 1.5 cm). Te external surface is green yellow, wrinkled with a small amount of attached fibroadipose tissue. The lumen is filled with a green viscile bile. No calculi grossly appreciated. There are several adherent soft lesions (possible polyps) ranging from 0.2 cm to 0.5 cm in greatest dimension. A representative section of these lesions is submitted for frozen section as FSD1. The remainder of the mucosal surface is green-yellow, velvet-like and grossly unremarkable. Permanent representative sections are submitted as D2-D3.

Source: NCI Genomic Data Commons file 5e53b684-4899-4687-9e8e-8f934f9d3c88 (TCGA-3A-A9IV.A0D8875D-EBF7-4D76-945F-3CDFB6B9A351.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).